Somatic mutation profile of tumor specimen TCGA-FY-A40L-01A (aliquot TCGA-FY-A40L-01A-11D-A23M-08) from TCGA case TCGA-FY-A40L, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 55.4 years (20,243 days).
Specimen TCGA-FY-A40L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89a622a8-cd5d-4b7e-8996-8d9d14407af2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A40L-10A (Blood Derived Normal), aliquot TCGA-FY-A40L-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a21eb4d7-fa00-4118-9a10-b183b7f071d8

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Frame Shift Del 2, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACAD9 | c.767A>T p.N256I | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV100458914; called by muse, mutect2, varscan2
- C11orf45 | c.279G>A p.V93= | Splice Region (SNP) | VAF 20/91 reads (22%) | catalogued as COSV100171467; called by muse, mutect2, varscan2
- CAD | c.3866C>T p.A1289V | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99254342; called by muse, mutect2, varscan2
- CEP164 | c.2222A>G p.N741S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV99632483; called by muse, mutect2, varscan2
- COQ6 | c.1389G>A p.M463I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99473719; called by muse, mutect2, varscan2
- IGFN1 | c.1636A>G p.I546V (on ENST00000295591 / NM_001367841.1; = p.I3003V on NM_001164586.2) | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.074); catalogued as COSV99811009; called by muse, mutect2, varscan2
- PDZD2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV99223535; called by muse, mutect2, varscan2
- PLK2 | c.17C>G p.T6S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.027); catalogued as COSV99955760; called by muse, mutect2, varscan2
- RCOR2 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100036028; called by muse, mutect2, varscan2
- THBS2 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100827554; called by muse, mutect2, varscan2
- TNFSF15 | c.437A>T p.D146V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100928300; called by muse, mutect2, varscan2
- USP24 | c.2168C>T p.T723I | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV99598740; called by muse, mutect2
- DDX28 | c.1208del p.F403Sfs*8 | Frame Shift Del (DEL) | VAF 48/135 reads (36%) | called by mutect2, pindel, varscan2
- TLR2 | c.1275del p.H426Ifs*13 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | called by mutect2, pindel, varscan2
- CASP7 | c.519C>G p.T173= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100614767; called by muse, mutect2, varscan2
- CCDC88B | c.367T>C p.L123= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as rs755212385, COSV100104947, COSV57267702; called by muse, mutect2, varscan2
